Somatic mutation profile of tumor specimen ALCH-AEOD-TTP1-A (aliquot ALCH-AEOD-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AEOD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.3 years (23,474 days).
Specimen ALCH-AEOD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 939bacae-a4d9-42c1-833a-4e00432c2149.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEOD-NB1-A (Blood Derived Normal), aliquot ALCH-AEOD-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/467c9978-e991-4d20-958d-b81b46dfc7a0

The open-access MAF lists 37 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 6, Intron 3, In Frame Del 2, Frame Shift Ins 2, RNA 2, Nonsense Mutation 2, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY5 | c.2740G>A p.V914M | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs781580481, COSV100568054; called by muse, mutect2, varscan2
- ATP1A4 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 72/498 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs752839307; called by muse, mutect2, varscan2
- CAPN7 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 48/342 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs746460305; called by muse, varscan2
- COL3A1 | c.1006G>T p.G336C | Missense Mutation (SNP) | VAF 102/654 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58589044; called by muse, mutect2, varscan2
- FSIP2 | c.3252dup p.L1085Tfs*5 | Frame Shift Ins (INS) | VAF 38/287 reads (13%) | catalogued as rs1559025750; called by mutect2, pindel, varscan2
- MMS19 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 49/310 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs756645131; called by muse, mutect2, varscan2
- PALD1 | c.1393G>A p.V465M | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as rs751312004, COSV99698525; called by muse, mutect2, varscan2
- PASK | c.3079G>A p.V1027M | Missense Mutation (SNP) | VAF 105/826 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs917008838; called by muse, mutect2, varscan2
- SLC46A1 | c.478C>T p.L160F | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs1411766250; called by muse, mutect2, varscan2
- SRP54 | c.16C>G p.L6V | Missense Mutation (SNP) | VAF 109/468 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53739231; called by muse, varscan2
- VPS13C | c.10439G>T p.R3480L (on ENST00000644861 / NM_020821.3; = p.R3437L on NM_017684.5) | Missense Mutation (SNP) | VAF 43/291 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV51318719; called by muse, mutect2, varscan2
- ATM | c.8182_8183insAA p.M2728Kfs*24 | Frame Shift Ins (INS) | VAF 80/535 reads (15%) | called by mutect2, pindel, varscan2
- BCORL1 | c.423G>A p.W141* | Nonsense Mutation (SNP) | VAF 11/194 reads (6%) | called by muse, mutect2
- CRLF3 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DSG4 | c.3113C>T p.T1038I | Missense Mutation (SNP) | VAF 52/387 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EPB41 | c.915_935del p.L305_D312delinsF (on ENST00000343067 / NM_001166005.2; = p.L96_D103delinsF on NM_004437.4) | In Frame Del (DEL) | VAF 46/593 reads (8%) | called by mutect2, pindel
- FXR1 | c.198G>A p.E66= | Splice Region (SNP) | VAF 63/284 reads (22%) | called by muse, mutect2, varscan2
- NUP98 | c.4892A>T p.H1631L (on ENST00000359171 / NM_001365126.1; = p.H1614L on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/514 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- PPP6R1 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2
- RAB19 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 55/333 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- RNF145 | c.1793G>A p.G598E (on ENST00000424310 / NM_001199383.2; = p.G626E on NM_144726.2) | Missense Mutation (SNP) | VAF 60/736 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2
- SGK2 | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- THAP8 | c.183C>G p.H61Q | Missense Mutation (SNP) | VAF 41/255 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNRC6B | c.3432T>A p.N1144K | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.761); called by muse, mutect2
- ZC3H7A | c.1022_1024del p.F341del | In Frame Del (DEL) | VAF 39/356 reads (11%) | called by mutect2, pindel, varscan2
- MYO5A | c.3882A>T p.I1294= | Silent (SNP) | VAF 62/689 reads (9%) | called by muse, mutect2
- PER2 | c.1704C>T p.P568= | Silent (SNP) | VAF 101/718 reads (14%) | catalogued as rs780990266; called by muse, mutect2, varscan2
- PGAP4 | c.123G>T p.L41= | Silent (SNP) | VAF 42/291 reads (14%) | catalogued as rs1177586291; called by muse, mutect2, varscan2
- RAD18 | c.123T>C p.C41= | Silent (SNP) | VAF 54/380 reads (14%) | catalogued as rs368372003; called by muse, varscan2
- TGFB1 | c.240G>A p.L80= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs199592796; called by muse, mutect2
- TMEM35A | c.435G>A p.L145= | Silent (SNP) | VAF 52/105 reads (50%) | called by muse, mutect2, varscan2
- AP003393.1 | n.515-752G>A | Intron (SNP) | VAF 104/536 reads (19%) | catalogued as rs747412536; called by muse, mutect2, varscan2
- ARMCX4 | c.1039-3204A>G | Intron (SNP) | VAF 52/222 reads (23%) | called by muse, mutect2, varscan2
- CCDC113 | c.-23G>A | 5'UTR (SNP) | VAF 50/345 reads (14%) | catalogued as COSV99540844; called by muse, mutect2, varscan2
- CLCN2 | c.1171-22T>C | Intron (SNP) | VAF 52/420 reads (12%) | catalogued as rs1340428543; called by muse, mutect2, varscan2
- HERC2P3 | n.1409G>A | RNA (SNP) | VAF 68/1604 reads (4%) | catalogued as rs771304572; called by muse, mutect2
- PRORY | n.479G>A | RNA (SNP) | VAF 85/305 reads (28%) | catalogued as rs758469324; called by muse, mutect2, varscan2
